CGCI case HTMCP-03-06-02428 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/29d2a6dd-fb70-46ca-bfa3-0a00025970b7

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 513 days (1.4 years).

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 57.5 years (20,993 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; AJCC clinical T: T2b; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 513 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 19 days; Days to treatment end: 51 days; Number of cycles: 3; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 350 days; Disease response: Tumor Free.
- Days to follow up: 513 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: AIDS risk factors: Wasting Syndrome.
- Day 0: Weight: 54 kg; Height: 160.2 cm; BMI: 21; CD4 count: 501; Haart treatment indicator: Yes; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Perimenopausal; Pregnant at diagnosis: No.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02428-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02428-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Pregnancies count miscarriage: 1; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2008; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Prior aids conditions: Wasting syndrome, due to HIV.
- Follow-up form 1: Tumor status: Tumor free.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 3; Treatment best response: Clinical Progressive Disease.
